Somatic mutation profile of tumor specimen 10c2d629-0287-4511-ac25-f29031 (aliquot 10c2d629-0287-4511-ac25-f29031_D6) from CPTAC case 04OV036, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV.
Specimen 10c2d629-0287-4511-ac25-f29031: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62c120be-a679-40df-830a-bd7d0f7f704e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen f4bcf727-f39b-4b0d-aaa5-cdcf0b (Blood Derived Normal), aliquot f4bcf727-f39b-4b0d-aaa5-cdcf0b_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3115ccbc-6d3a-4124-ae35-1cebfcbe83c4

The open-access MAF lists 108 somatic variants for this specimen: 66 protein-altering or splice-affecting, 26 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 26, Intron 8, RNA 3, Nonsense Mutation 3, 3'UTR 2, Splice Site 2, 3'Flank 1, Frame Shift Del 1, Translation Start Site 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPATA7 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as rs140287375, CM113103, COSV50417544; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 28/131 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ALG10 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 32/285 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs776095952; called by mutect2, varscan2
- ANKRD36 | c.4274T>C p.I1425T | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs17415756; called by mutect2, varscan2
- C22orf15 | c.64G>C p.V22L | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as rs766497620; called by muse, mutect2, varscan2
- CACNA1D | c.1780G>A p.V594M (on ENST00000350061 / NM_001128840.3; = p.V614M on NM_000720.4) | Missense Mutation (SNP) | VAF 136/326 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55441401; called by muse, mutect2, varscan2
- CDH13 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs761139160; called by mutect2, varscan2
- CLASRP | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.01); catalogued as rs139553242; called by muse, mutect2, varscan2
- DIAPH1 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.959); catalogued as rs1220646059; called by muse, mutect2, varscan2
- DNM3 | c.341G>C p.G114A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs538785687; called by mutect2, varscan2
- DRP2 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745315795, COSV100871981; called by muse, mutect2, varscan2
- FAT3 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs759513599, COSV53079368, COSV53086015; called by muse, mutect2, varscan2
- FEZ1 | c.452A>G p.E151G | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV99630908; called by muse, mutect2, varscan2
- GAGE10 | c.236T>G p.V79G | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs202030448, COSV68163700, COSV68163782; called by muse, varscan2
- GFM1 | c.228G>T p.M76I | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.17); catalogued as rs746234485; called by muse, mutect2, varscan2
- GP2 | c.848C>T p.A283V (on ENST00000381362 / NM_001007240.3; = p.A280V on NM_001502.4) | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as rs1446529488; called by muse, mutect2
- GRID1 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.712); catalogued as rs368060520; called by muse, mutect2, varscan2
- LRRC37A3 | c.3058G>T p.V1020L | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs566295029; called by mutect2, varscan2
- OR2M3 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 148/248 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as rs774501459; called by muse, varscan2
- OR5D14 | c.896T>G p.V299G | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100161981; called by muse, mutect2, varscan2
- PCDHA7 | c.1119C>G p.S373R | Missense Mutation (SNP) | VAF 43/512 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV65343743; called by muse, mutect2
- SERPINB4 | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1448356421; called by muse, mutect2
- SNAPC4 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 62/853 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs747332487, COSV53732299; called by muse, mutect2
- TUBA4B | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as COSV67526324; called by muse, mutect2, varscan2
- VAV1 | c.2010C>G p.L670= | Splice Region (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100408996, COSV58378523; called by muse, mutect2, varscan2
- VSIG4 | c.114T>A p.N38K | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs150979129; called by muse, mutect2, varscan2
- AASS | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADK | c.561T>A p.F187L (on ENST00000286621; = p.F170L on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ANGPT2 | c.561_566+27del p.X187_splice | Splice Site (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- ATG4A | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- BEX1 | c.129C>A p.Y43* | Nonsense Mutation (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2, varscan2
- BRD7 | c.1681A>C p.N561H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- C19orf44 | c.1585A>G p.K529E | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- CAPRIN1 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CENPE | c.6019G>C p.E2007Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CREB1 | c.534C>A p.S178R (on ENST00000432329 / NM_134442.5; = p.S164R on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- DHX57 | c.527T>G p.V176G | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EIF4G1 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 33/413 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); called by muse, mutect2
- GABRB1 | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- GLIPR1 | c.208G>C p.A70P | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- GLYATL2 | c.700C>A p.H234N | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, varscan2
- GPR101 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 171/509 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC16 | c.20995C>A p.P6999T | Missense Mutation (SNP) | VAF 106/308 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MYH2 | c.5530A>T p.K1844* | Nonsense Mutation (SNP) | VAF 128/314 reads (41%) | called by muse, mutect2, varscan2
- MYOCD | c.251A>G p.Q84R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- NOP9 | c.1409A>T p.Q470L | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- NOS1 | c.3946G>A p.A1316T | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOX4 | c.1561A>C p.I521L | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by mutect2, varscan2
- NPIPA3 | c.683T>C p.L228S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); called by mutect2, varscan2
- OR52M1 | c.612C>A p.S204R | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- PLBD2 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PPAT | c.949G>C p.D317H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- PYGM | c.1768+2T>A p.X590_splice | Splice Site (SNP) | VAF 87/362 reads (24%) | called by muse, mutect2, varscan2
- RP1L1 | c.5489A>T p.D1830V | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- S100A9 | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SHISA6 | c.1003C>A p.L335M (on ENST00000409168 / NM_001173461.1; = p.L386M on NM_207386.4) | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SLC4A2 | c.787C>G p.Q263E | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMG5 | c.302T>G p.I101S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SMIM20 | c.166_182del p.G56* | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- SNPH | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 55/462 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SPATA31A1 | c.1663A>G p.R555G | Missense Mutation (SNP) | VAF 37/845 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TCP11L1 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by mutect2, varscan2
- TENM4 | c.5830A>G p.I1944V | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- WNT8B | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZAN | c.6746T>A p.I2249N | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- ZZEF1 | c.5980G>C p.A1994P | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- BRD7 | c.1680G>A p.Q560= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs751773053, COSV54271315; called by muse, mutect2, varscan2
- CYP2C9 | c.975A>G p.E325= | Silent (SNP) | VAF 59/147 reads (40%) | called by muse, varscan2
- DACH2 | c.252C>T p.D84= | Silent (SNP) | VAF 116/413 reads (28%) | called by muse, mutect2, varscan2
- DMPK | c.615C>T p.R205= | Silent (SNP) | VAF 55/234 reads (24%) | called by muse, mutect2, varscan2
- DPY19L2 | c.1425T>C p.Y475= | Silent (SNP) | VAF 8/62 reads (13%) | called by mutect2, varscan2
- ERAP1 | c.18C>G p.L6= | Silent (SNP) | VAF 40/112 reads (36%) | called by muse, mutect2, varscan2
- GIPC1 | c.321G>C p.V107= | Silent (SNP) | VAF 34/124 reads (27%) | called by muse, mutect2, varscan2
- GJA9 | c.21T>A p.L7= | Silent (SNP) | VAF 12/73 reads (16%) | called by mutect2, varscan2
- GPR37L1 | c.1110C>T p.F370= | Silent (SNP) | VAF 48/319 reads (15%) | called by muse, varscan2
- HSD17B2 | c.369A>G p.E123= | Silent (SNP) | VAF 88/236 reads (37%) | called by muse, mutect2, varscan2
- IGKV1-12 | c.15C>T p.V5= | Silent (SNP) | VAF 290/2184 reads (13%) | called by muse, varscan2
- NFIC | c.510C>T p.G170= | Silent (SNP) | VAF 43/156 reads (28%) | catalogued as rs1472761540; called by muse, mutect2, varscan2
- NOX4 | c.1563A>T p.I521= | Silent (SNP) | VAF 14/130 reads (11%) | called by mutect2, varscan2
- PLIN5 | c.1242C>G p.A414= | Silent (SNP) | VAF 32/106 reads (30%) | called by muse, mutect2, varscan2
- PPT1 | c.48A>G p.P16= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as rs1003007171; called by muse, mutect2, varscan2
- RANBP3 | c.1680C>T p.D560= (on ENST00000340578 / NM_007322.3; = p.D555= on NM_003624.3) | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as rs560054817; called by muse, mutect2, varscan2
- RASGRP1 | c.216T>C p.S72= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs559430624, COSV60364820; called by muse, mutect2, varscan2
- RRAS2 | c.393G>A p.L131= | Silent (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- SEPTIN4 | c.1263C>T p.Y421= | Silent (SNP) | VAF 43/182 reads (24%) | catalogued as rs774643083; called by muse, mutect2, varscan2
- SHANK3 | c.2013A>T p.P671= | Silent (SNP) | VAF 57/178 reads (32%) | called by muse, mutect2, varscan2
- SLC4A4 | c.1791C>T p.I597= (on ENST00000264485 / NM_001098484.3; = p.I553= on NM_003759.4) | Silent (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- TAF3 | c.1158G>A p.T386= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as rs117733404; called by muse, mutect2, varscan2
- TCHHL1 | c.1245A>G p.L415= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as rs771031574; called by muse, mutect2, varscan2
- TRIM51 | c.771T>C p.S257= | Silent (SNP) | VAF 40/344 reads (12%) | called by mutect2, varscan2
- UBR4 | c.10407G>T p.V3469= | Silent (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- WDR55 | c.861G>A p.V287= | Silent (SNP) | VAF 55/206 reads (27%) | called by muse, mutect2, varscan2
- ACSM2B | c.597-248G>C | Intron (SNP) | VAF 8/55 reads (15%) | catalogued as rs1400417333; called by mutect2, varscan2
- AGBL4 | c.*61A>T | 3'UTR (SNP) | VAF 31/116 reads (27%) | called by muse, mutect2, varscan2
- CCNYL2 | n.624-2700G>A | Intron (SNP) | VAF 45/182 reads (25%) | called by muse, mutect2, varscan2
- CEP170P1 | n.1856A>C | RNA (SNP) | VAF 33/215 reads (15%) | called by mutect2, varscan2
- CEP170P1 | n.4582A>G | RNA (SNP) | VAF 42/153 reads (27%) | called by mutect2, varscan2
- FAAP20 | chr1:2186093 T>C | 3'Flank (SNP) | VAF 34/117 reads (29%) | called by muse, mutect2, varscan2
- FAM153A | c.*12+34G>C | Intron (SNP) | VAF 64/298 reads (21%) | called by muse, varscan2
- GCNT7 | c.-268A>C | 5'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- GYS1 | c.*944C>G | 3'UTR (SNP) | VAF 72/295 reads (24%) | called by muse, mutect2, varscan2
- HAUS7 | c.960+507A>G | Intron (SNP) | VAF 31/138 reads (22%) | called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.280G>C | RNA (SNP) | VAF 46/416 reads (11%) | catalogued as rs3955534; called by mutect2, varscan2
- SLC25A29 | chr14:100307891 A>G | 5'Flank (SNP) | VAF 39/132 reads (30%) | called by muse, mutect2, varscan2
- SPEG | c.389-1515C>G | Intron (SNP) | VAF 61/214 reads (29%) | catalogued as rs527794281; called by muse, mutect2, varscan2
- SRL | c.62-2970G>A | Intron (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- TRPM2 | c.3462-1346C>G | Intron (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- UGGT1 | c.195-799T>C | Intron (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
